Surgical pathology report (de-identified scan), TCGA case TCGA-43-A56V, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-A56V-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

ICD-O-3
Carcinoma, Squamous Cell NOS
8070/3
Site
① Lung, middle lobe
C34.2
9W 11/29/12

Procedure:

Diagnosis

A. Lymph node, level 11, biopsy:

Lymph node fragments, negative for malignancy

B. Lung, right middle lobe, lobectomy:

Squamous cell carcinoma, moderately differentiated, 4.5 cm, contiguous with pleura

Bronchial margin is negative for malignancy

Tumor is present in the pulmonary parenchyma surrounding the vascular resection margins

C. Lymph nodes R4, biopsy:

Metastatic squamous cell carcinoma in multiple lymph nodes with extranodal tumor

Microscopic Description:

Microscopic examination performed.

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Primary tumor (pT): Tumor is 4.5 cm in size and involves visceral pleura (pT2a)

Margins of resection: The bronchial margin is negative for tumor.

However tumor is present in deep pulmonary parenchyma supporting the vascular resection margins

Direct extension of tumor: Tumor invades visceral pleura and the "hilar area" of the right middle lobe

Venous (large vessel) invasion: Not identified

Arterial (large vessel) invasion: Not identified

Lymphatic (small vessel) invasion: Present in block B-1 adjacent to the venous resection margins

Regional lymph nodes (pN): Multiple lymph node fragments are positive in the C sample. (pN2)

Distant metastasis (pM): [Not applicable]

Other findings: An elastic stain was evaluated of blocks B2 and B3

Specimen

A. Level XI lymph node

B. Right middle lobe

C. R4

Clinical Information

Lung mass

Gross Description

A. Received in formalin labeled "Level XI node" are multiple pink black irregular soft friable tissue fragments which have an aggregate measurement of 2.5 x 2.0 x 0.5 cm. AS1.

B. Received fresh and subsequently fixed in formalin labeled "right middle lobe" is a 14.0 x 7.5 x 4.5 cm lobe of lung which is partially covered with pink red smooth glistening pleural surface. The specimen has an umbilication measuring 1.5 x 1.0 cm. This area is inked orange. The specimen is sectioned in this area to show a 4.5 x 3.5 x 3.5 cm white gray tan irregular mass contiguous with the umbilication

[page 2 of 2]
C. Received fresh and subsequently fixed in formalin labeled "R4" is a 2.5 x 2.2 x 0.4 cm aggregate of pink white black irregular soft friable tissue fragments. AS- 1.

C. Received fresh and subsequently fixed in formalin labeled "R4" is a 2.5 x 2.2 x 0.4 cm aggregate of pink white black irregular soft friable tissue fragments. AS- 1.

[illegible]

Source: NCI Genomic Data Commons file ce3ac99c-2be6-439f-a062-1560f579fa37 (TCGA-43-A56V.716CE78F-14FC-43DE-96F9-A12874CA9648.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).